Somatic mutation profile of tumor specimen TCGA-CN-6994-01A (aliquot TCGA-CN-6994-01A-11D-1912-08) from TCGA case TCGA-CN-6994, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 67.8 years (24,778 days).
Specimen TCGA-CN-6994-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 672218af-830a-4cd9-92b2-c876d474a901.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6994-10A (Blood Derived Normal), aliquot TCGA-CN-6994-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca40eda9-750a-41af-9b7a-dfdc6efb7145

The open-access MAF lists 121 somatic variants for this specimen: 89 protein-altering or splice-affecting, 26 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 26, Nonsense Mutation 4, RNA 3, In Frame Del 2, Splice Site 2, 5'UTR 2, Splice Region 1, Frame Shift Del 1, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 11/88 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 23/73 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKRD17 | c.6529G>C p.A2177P | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100429849; called by muse, mutect2, varscan2
- ARMC6 | c.83C>T p.S28F (on ENST00000392336; = p.S3F on NM_033415.4) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99523148; called by muse, mutect2, varscan2
- B4GALNT4 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as COSV100327832; called by muse, mutect2, varscan2
- BAZ2B | c.3745G>C p.E1249Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99681062; called by muse, mutect2, varscan2
- BCL11B | c.2519C>T p.T840M (on ENST00000357195 / NM_001282237.2; = p.T769M on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61733490; called by muse, mutect2, varscan2
- BTBD2 | c.537C>G p.Y179* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99724937; called by muse, mutect2, varscan2
- CEBPZ | c.2029G>C p.E677Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.124); catalogued as COSV99305402; called by muse, mutect2, varscan2
- CEP57 | c.1465A>G p.N489D | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV100334805; called by muse, mutect2, varscan2
- CLSTN2 | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.089); catalogued as rs139860767; called by muse, mutect2, varscan2
- CRTAP | c.944C>A p.A315D | Missense Mutation (SNP) | VAF 60/94 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100310182; called by muse, mutect2, varscan2
- CSHL1 | c.20C>A p.T7K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as rs1335138733, COSV51989691, COSV99368153; called by muse, mutect2, varscan2
- CUX2 | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs1238553608; called by muse, mutect2, varscan2
- DGKB | c.2347G>C p.G783R | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs763503657, COSV99342759; called by muse, mutect2
- DNAAF3 | c.1625G>C p.*542Sext*4 (on ENST00000524407 / NM_001256715.2; = p.*589Sext*4 on NM_178837.4) | Nonstop Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100787995; called by muse, mutect2, varscan2
- EFCAB5 | c.3044G>A p.G1015E | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs954918050, COSV100300630; called by muse, mutect2, varscan2
- EPS15 | c.1375C>G p.Q459E | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV100869594; called by muse, mutect2, varscan2
- FABP12 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV100846582; called by muse, mutect2, varscan2
- FLG | c.5416T>G p.S1806A | Missense Mutation (SNP) | VAF 101/522 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.746); catalogued as COSV100912021; called by muse, mutect2, varscan2
- FRY | c.1651+2T>A p.X551_splice | Splice Site (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100969817; called by muse, mutect2
- GALR2 | c.858C>A p.C286* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as rs763666379, COSV100135650, COSV57164125; called by muse, mutect2
- GRIN3A | c.3194C>A p.A1065E | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.101); catalogued as COSV100701748, COSV62452946; called by muse, mutect2, varscan2
- HACE1 | c.1316C>G p.A439G | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99494192; called by muse, mutect2, varscan2
- HELZ | c.4367C>A p.P1456H | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV100699006; called by muse, mutect2, varscan2
- ICE1 | c.1892C>T p.S631F | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs1373202466, COSV99665513; called by muse, mutect2, varscan2
- IGDCC4 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs949337865, COSV61539114; called by muse, mutect2, varscan2
- IGHV3-43 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as rs1211939727; called by muse, mutect2
- IL18R1 | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV52126917, COSV99295440; called by muse, mutect2, varscan2
- ILK | c.979-1G>A p.X327_splice | Splice Site (SNP) | VAF 8/116 reads (7%) | catalogued as COSV54992077; called by muse, mutect2
- IREB2 | c.437G>C p.G146A | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.727); catalogued as COSV99359678; called by muse, mutect2, varscan2
- JADE2 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV99253589; called by mutect2, varscan2
- KCND2 | c.259C>G p.R87G | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100478099, COSV58583837; called by muse, mutect2, varscan2
- KCNN1 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs944927086, COSV55836946; called by muse, mutect2, varscan2
- KIAA1549L | c.2336C>A p.T779K (on ENST00000321505; = p.T1076K on NM_012194.3) | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99684283; called by muse, mutect2, varscan2
- KRI1 | c.1761C>G p.F587L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV100470390; called by muse, mutect2, varscan2
- LPA | c.4391G>T p.R1464L | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs767564396, COSV60310772, COSV60312703; called by muse, mutect2, varscan2
- LRP1B | c.5510C>T p.S1837F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.034); catalogued as COSV67284552; called by muse, mutect2, varscan2
- LRRTM3 | c.358A>G p.R120G | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs1387292307, COSV100791886; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1882C>A p.Q628K | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99571723; called by muse, mutect2
- MERTK | c.675G>C p.E225D | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.138); catalogued as COSV99775180; called by muse, mutect2, varscan2
- MYEF2 | c.1478C>G p.A493G | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.992); catalogued as COSV99982044; called by muse, mutect2, varscan2
- NCAPH | c.1235G>T p.G412V | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as COSV99546135; called by muse, mutect2, varscan2
- NEU1 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1016129010, COSV99999229; called by muse, mutect2, varscan2
- NOTCH1 | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.85); catalogued as COSV53056478, COSV53094964; called by muse, mutect2, varscan2
- NUP205 | c.1278G>C p.Q426H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs765422001, COSV53663258, COSV99607464; called by muse, mutect2, varscan2
- OR10G4 | c.588G>T p.M196I | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV100304946; called by muse, mutect2, varscan2
- OSBPL7 | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.557); catalogued as COSV99136971; called by muse, mutect2, varscan2
- PA2G4 | c.69G>A p.M23I | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs144476801; called by muse, mutect2, varscan2
- PARP3 | c.831G>T p.E277D | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV99232648; called by muse, mutect2, varscan2
- PCDH15 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.542); catalogued as rs765508390, COSV100226388; called by muse, mutect2
- PIK3CG | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1370328855, COSV63246438, COSV63251375; called by muse, mutect2, varscan2
- PRLR | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99184696; called by muse, mutect2, varscan2
- PROS1 | c.1463C>G p.S488C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV101260767; called by muse, mutect2
- RAD51 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99139348; called by muse, mutect2, varscan2
- RET | c.1846_1848del p.E616del | In Frame Del (DEL) | VAF 9/28 reads (32%) | catalogued as rs377767399; called by pindel, varscan2
- RNF20 | c.2380C>T p.Q794* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV101206572; called by muse, mutect2
- RNF213 | c.1773G>C p.W591C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.99); catalogued as COSV100173870; called by muse, mutect2, varscan2
- RNF213 | c.11530G>A p.E3844K | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100301313; called by muse, mutect2, varscan2
- SCN4A | c.2469G>C p.Q823H | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101438626; called by muse, mutect2
- SERPINC1 | c.277A>C p.T93P | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.184); catalogued as COSV62930207; called by muse, mutect2, varscan2
- SERPINI1 | c.678G>T p.G226= | Splice Region (SNP) | VAF 18/52 reads (35%) | catalogued as COSV99855348; called by muse, mutect2, varscan2
- SIM1 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as rs374696271, COSV53492540; called by muse, mutect2, varscan2
- SLC10A5 | c.562A>C p.M188L | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV101594266; called by muse, mutect2, varscan2
- SLC25A31 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs935825488, COSV99028863; called by muse, mutect2, varscan2
- SLC4A10 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.41); catalogued as COSV55795698; called by muse, mutect2, varscan2
- SLCO6A1 | c.672C>G p.F224L | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV101134878, COSV65809909; called by muse, mutect2, varscan2
- SOCS6 | c.1384A>G p.I462V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs370311027; called by muse, mutect2, varscan2
- SULF1 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV52694661, COSV99484127; called by muse, mutect2
- TBC1D2B | c.1368G>T p.K456N | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV100317651; called by muse, mutect2, varscan2
- TBCEL | c.1123C>G p.L375V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1285719968, COSV99412384; called by muse, mutect2, varscan2
- TDP1 | c.1754A>G p.D585G | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs148839664, COSV59643583; called by muse, mutect2
- TESPA1 | c.1310G>T p.R437I (on ENST00000316577 / NM_001098815.3; = p.R299I on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as rs773580545, COSV100345560, COSV57258989; called by muse, mutect2, varscan2
- THAP4 | c.1442G>C p.R481T | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100398310; called by muse, mutect2, varscan2
- TMEM184C | c.303G>C p.L101F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99669773; called by muse, mutect2, varscan2
- TNC | c.6537C>G p.I2179M | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100406156; called by muse, mutect2, varscan2
- TP53 | c.848G>C p.R283P | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs371409680, CM021154, COSV52693421, COSV52700134, COSV52964971; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPO | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61111439; called by muse, mutect2, varscan2
- WDR19 | c.2038G>T p.E680* | Nonsense Mutation (SNP) | VAF 32/68 reads (47%) | catalogued as COSV99975868; called by muse, mutect2, varscan2
- ZBTB32 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 188/520 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99386232; called by muse, mutect2, varscan2
- ZFAT | c.2555A>T p.N852I | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100914878; called by muse, mutect2, varscan2
- ZIC4 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as COSV101268113; called by muse, mutect2, varscan2
- ZNF420 | c.1986G>C p.Q662H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100421476; called by muse, mutect2, varscan2
- ZNF567 | c.1073C>A p.T358N (on ENST00000536254 / NM_001322913.1; = p.T327N on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.196); catalogued as COSV100658957; called by muse, mutect2, varscan2
- ZNF791 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV100589157; called by muse, mutect2
- ZNF827 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65225827, COSV65226502; called by muse, mutect2, varscan2
- ZNF846 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV101194372; called by muse, mutect2, varscan2
- DNAH17 | c.8464_8477del p.V2822Pfs*13 | Frame Shift Del (DEL) | VAF 14/116 reads (12%) | called by mutect2, pindel
- EXOC6 | c.1326_1328del p.E442del | In Frame Del (DEL) | VAF 7/46 reads (15%) | called by pindel, varscan2
- ANKRD44 | c.360C>T p.V120= | Silent (SNP) | VAF 42/190 reads (22%) | catalogued as COSV99985854; called by muse, varscan2
- AQP1 | c.63G>T p.T21= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100311031, COSV61266262; called by muse, mutect2, varscan2
- CCDC146 | c.1143T>C p.T381= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV99593054; called by muse, mutect2, varscan2
- CDCP2 | c.498G>A p.P166= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs776452856, COSV100313644, COSV61283800; called by muse, mutect2, varscan2
- CEP250 | c.5655G>A p.L1885= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100699135; called by muse, mutect2, varscan2
- CMTR1 | c.1203C>T p.F401= | Silent (SNP) | VAF 38/205 reads (19%) | catalogued as COSV100990920, COSV65090974; called by muse, mutect2, varscan2
- CNTLN | c.1995C>G p.L665= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as rs1037432366, COSV99265396; called by muse, mutect2, varscan2
- KAT6A | c.4428G>A p.A1476= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as rs369778154, COSV99705733; called by muse, mutect2, varscan2
- KCNJ15 | c.471G>A p.E157= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100154362, COSV60810642; called by muse, mutect2, varscan2
- L3MBTL2 | c.1860G>A p.K620= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99346114; called by muse, mutect2, varscan2
- NFYA | c.1005C>T p.A335= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as rs377013862; called by muse, mutect2, varscan2
- NKTR | c.162G>C p.G54= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1181329631, COSV99236235; called by muse, mutect2, varscan2
- NLRC3 | c.834C>T p.G278= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs774098538, COSV100073295; called by muse, mutect2, varscan2
- NOS2 | c.2694C>T p.S898= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs777207049, COSV100569854; called by muse, varscan2
- PALM2AKAP2 | c.1321C>A p.R441= (on ENST00000259318 / NM_001136562.3; = p.R672= on NM_007203.5) | Silent (SNP) | VAF 45/126 reads (36%) | catalogued as COSV99395618; called by muse, mutect2, varscan2
- PCDH1 | c.1200G>C p.G400= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as COSV99746837; called by muse, mutect2, varscan2
- PCDHA1 | c.1404C>T p.N468= | Silent (SNP) | VAF 53/110 reads (48%) | catalogued as COSV100974447; called by muse, mutect2, varscan2
- PKD1L1 | c.3711C>T p.H1237= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs753208411, COSV99221126; called by muse, mutect2, varscan2
- RAD23B | c.507T>C p.G169= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV100787764; called by muse, mutect2, varscan2
- RHOT2 | c.1725C>T p.A575= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1337852759, COSV99558898; called by muse, mutect2
- SLC35G2 | c.174G>C p.L58= | Silent (SNP) | VAF 25/214 reads (12%) | catalogued as COSV101262087; called by muse, mutect2, varscan2
- SORCS3 | c.3189C>A p.P1063= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100865599; called by muse, mutect2, varscan2
- STC1 | c.627T>G p.A209= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV99282700; called by muse, mutect2, varscan2
- SUZ12 | c.618T>C p.V206= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV100497053; called by mutect2, varscan2
- TNRC6C | c.1248G>A p.T416= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as rs569253210, COSV100050573; called by muse, mutect2, varscan2
- ZNF766 | c.1308G>A p.E436= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as COSV100765437; called by muse, mutect2
- ALAS2 | c.-15-1766A>T | Intron (SNP) | VAF 13/31 reads (42%) | catalogued as COSV100238571; called by muse, mutect2, varscan2
- CLEC12A | c.-1A>C | 5'UTR (SNP) | VAF 31/72 reads (43%) | catalogued as COSV100429655; called by muse, mutect2, varscan2
- HDAC7 | c.-51G>A | 5'UTR (SNP) | VAF 9/31 reads (29%) | catalogued as rs780709510, COSV99315357; called by muse, mutect2, varscan2
- MIR134 | n.24G>C | RNA (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- SNORD116-16 | n.56A>T | RNA (SNP) | VAF 36/198 reads (18%) | called by muse, mutect2, varscan2
- XIST | n.8291C>G | RNA (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
